Surgical pathology report (de-identified scan), TCGA case TCGA-GL-A59T, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma), tissue source site ABS - IUPUI, specimen TCGA-GL-A59T-01A (Primary Tumor).

[page 1 of 2]
Operative Procedure:
Left laparoscopic radical nephrectomy

Specimen Received:
Left kidney

Final Pathologic Diagnosis:
Kidney, left, radical nephrectomy:

ICD-O 3
Carcinoma, papillary renal cell
8260/3
Site: @ Kidney NOS C64.9
Jco 1/2/13

Tumor histologic type: Papillary renal cell carcinoma type 1,
multifocal (5 tumors) and clear cell renal cell
carcinoma (1 tumor)

Sarcomatoid features (%): Not identified

Tumor size: 6.7 cm (greatest dimension, largest papillary renal
cell carcinoma)

Other dimensions: Smaller foci of papillary renal cell carcinoma
(4 tumors, ranging from 0.6 to 1.7 cm)

Small focus of clear cell renal cell carcinoma (0.8 cm;
slide A11) per TSS - clear cell component not observed by screening pathologist at TSS.

Macroscopic extent of tumor: Confined to the kidney

Focality: Multifocal

Number of tumors: 6

Fuhrman grade: 2 of 4

Microscopic extent of tumor:

Perinephric fat invasion: Not identified

Renal sinus invasion: Not identified

Other: Not applicable

Renal vein involvement: Not identified

Adrenal gland present: No

Cancer at resection margin: No

Pathologic findings in nonneoplastic kidney: Numerous papillary adenomas

Hilar lymph nodes present: None

Pathologic stage pT1b pNX pM-not applicable

The examination of this case material and the preparation of this report were

Gross Description:

The specimen is received in formalin labeled with the patient's name, and labeled "left kidney."

Specimen components and dimensions: The specimen consists of a left kidney
received with a moderate amount of attached fat. The specimen has overall
dimensions of 23.4 x 8.7 x 5.2 cm. The renal parenchyma has dimensions of 14.2 x
6.4 x 3.8 cm. An adrenal gland is not present. The specimen is received
previously inked and incised.

Size, appearance, and location of tumor: The specimen is remarkable for
numerous nodules/masses that range from 0.2 x 0.2 by less than 0.2 cm to 6.7 x

[page 2 of 2]
5.9 x 4.4 cm. The dominate mass resides within the lower pole. The masses are yellow-orange to red-brown, granular and homogenous to variegated and focally hemorrhagic. These nodules/masses range from ill defined to well defined and encapsulated. The total number of nodules/masses is approximately 12.

Renal capsule/renal sinus: Some of the nodules/masses extend to, but not beyond the capsule. The renal sinus fat does not grossly appear to be invaded.

Renal vein: The renal vein is not invaded and is grossly negative at the margin.

Lymph nodes (size, number, & location): An exhaustive search of the hilar fat to include the use of palpation and chemical clearing agent reveals no grossly appreciable lymph nodes.

Other findings: Additionally, there are a few cysts present that range from minute to 1.2 cm in greatest dimension. The cysts contain gray-yellow, serous fluid. The cortical surface is red-brown, granular with numerous ill defined, yellow-orange granular foci, which are grossly similar to the aforementioned nodules/masses. The renal parenchyma is red-brown with an ill defined to well defined corticomedullary border and a cortical thickness that maximizes at approximately 0.5 cm. Additionally, there are a few ill defined, yellow-orange granular foci present, which are grossly similar to the aforementioned nodules/masses. Some of the papillary tips are hemorrhagic. The urothelium is gray-white, smooth and glistening with some edema.

Blocks submitted:

- 1 vascular and ureter margins en face;
- 2-5 dominant nodule/mass to include renal sinus fat in cassettes 2-3 and capsule and inked external surface in cassettes 4 and 5;
- 6-9 smaller nodules/masses to include renal sinus fat in cassettes 6-7 and capsule and inked external surface in cassettes 8 and 9;
- 10 ill defined, yellow-orange granular foci;
- 11 cysts;
- 12 hemorrhagic papillary tip;
- 13 normal most renal parenchyma and urothelium.

Gross images have been taken of the specimen.

Microscopic Description:

The final diagnosis of each specimen incorporates the microscopic examination findings.

END OF REPORT

Taken: DOB: (Age: Gender: M

PIPA Discrepancy		
Path Malignancy History		
Quarantine/Infectious Primary		

Source: NCI Genomic Data Commons file 285db86e-e791-4afb-8d8a-4c143fc4ca09 (TCGA-GL-A59T.681C28DC-CE0A-400D-BF7E-0836C603C388.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).